TCGA case TCGA-A2-A3XZ — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Walter Reed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fe7f74b8-20f4-4471-91dc-4cca8c68e5c0

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 46 years; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 46.5 years (16,978 days); Year of diagnosis: 2009; Method of diagnosis: Core Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T1c; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, Left Upper Inner / Breast, Left Upper Outer.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 3; Micrometastasis present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Docetaxel; Days to treatment start: 97 days; Days to treatment end: 202 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Trastuzumab; Days to treatment start: 97 days; Days to treatment end: 423 days (1.2 years); Treatment outcome: Complete Response.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 973 days (2.7 years); Disease response: Tumor Free.
- Days to follow up: 1,165 days (3.2 years); Disease response: Tumor Free.
- Days to follow up: 1,532 days (4.2 years); Disease response: Tumor Free.

Molecular and laboratory tests
- ERBB2 (IHC): Positive; Staining intensity value: 3+.
- ESR1 (IHC): Negative.
- PGR (IHC): Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-A2-A3XZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 1,100 mg.
  Slide TCGA-A2-A3XZ-01A-04-TSD: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 85; Percent normal cells: 5; Percent necrosis: 3; Percent stromal cells: 52; Percent lymphocyte infiltration: 6; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-A2-A3XZ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-A2-A3XZ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: Tumor free; Lymph nodes examined: Yes; Axillary staging method: Sentinel node biopsy alone; Surgical procedure first: Simple Mastectomy; Histologic diagnosis: Infiltrating Ductal Carcinoma; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); Micromet detection by IHC: Yes; Her2 IHC score: 3+; Method initial path diagnosis: Core needle biopsy; Prospective collection: No; Retrospective collection: Yes; New tumor event diagnosis indicator: No.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Left Upper Inner Quadrant; Anatomic organ subdivision: Left Upper Outer Quadrant.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,532 days; disease-specific survival: no event (censored), 1,532 days; disease-free interval: no event (censored), 1,532 days; progression-free interval: no event (censored), 1,532 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-A2-A3XZ-01A-42D-A238-01): tumor purity 0.27, ploidy 2.25, whole-genome doublings 0.
